Gene-level copy-number profile of tumor specimen TCGA-VD-A8KJ-01A from TCGA case TCGA-VD-A8KJ, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.6 years (19,562 days).
Specimen TCGA-VD-A8KJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.25cdafa6-48f1-46fa-bc26-b6944bee952a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8KJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19b053ce-9eb3-4fd0-a25c-34fe7315a65d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 4,295; copy number 2: 47,378; copy number 3: 4,501; copy number 4: 2,840; copy number 5: 652; copy number 6: 72; copy number 7: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8KJ-01A-11D-A39V-01): tumor purity 0.99, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:83,983,728–84,007,323, 1 gene (within-gene range 0–3): AL034347.1.
- chr6:111,227,747–111,259,034, 1 gene: AL360227.1.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 725 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 3–6): AC244205.1.
- chr2:88,857,161–89,990,221, 70 genes, copy number 6 (broad region; genes not listed).
- chr6:1,312,098–28,456,141, 578 genes, copy number 5 (broad region; genes not listed).
- chr6:63,615,827–63,616,361, 1 gene, copy number 5: RPL9P18.
- chr6:67,456,346–67,546,754, 3 genes, copy number 5: AL365503.1, RNA5SP208, RNU6-280P.
- chr6:71,532,070–71,551,643, 2 genes, copy number 5: AL035467.2, AL035467.1.
- chr6:73,130,646–73,263,196, 5 genes, copy number 5 (within-gene range 1–5): KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L.
- chr6:75,499,705–75,500,136, 1 gene, copy number 5: RPL26P20.
- chr6:75,601,509–75,718,281, 1 gene, copy number 5 (within-gene range 1–5): SENP6.
- chr6:75,644,084–75,655,299, 2 genes, copy number 5: RNU6-1016P, RN7SKP163.
- chr6:87,674,860–87,702,233, 1 gene, copy number 5: AKIRIN2.
- chr6:91,390,313–91,393,000, 1 gene, copy number 5: AL080284.1.
- chr6:91,726,810–92,888,581, 13 genes, copy number 5: MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1.
- chr6:98,210,020–98,214,683, 1 gene, copy number 5 (within-gene range 4–5): AL590727.1.
- chr6:100,881,471–100,890,338, 2 genes, copy number 5: AL133338.1, AL133338.2.
- chr6:105,096,822–105,169,952, 2 genes, copy number 5 (within-gene range 1–5): BVES, BVES-AS1.
- chr6:108,551,018–108,551,207, 1 gene, copy number 5: AL391646.1.
- chr6:110,020,011–110,040,241, 1 gene, copy number 5 (within-gene range 1–5): AL590009.1.
- chr6:111,091,213–111,091,332, 1 gene, copy number 5: RNU6-960P.
- chr6:112,616,703–112,826,470, 2 genes, copy number 5: PA2G4P5, AL360085.1.
- chr6:114,866,873–114,866,976, 1 gene, copy number 5: RNU6-475P.
- chr6:115,931,149–116,060,891, 3 genes, copy number 5 (within-gene range 1–5): FRK, AL357141.1, TPI1P3.
- chr6:120,686,621–120,686,742, 1 gene, copy number 5: RNA5SP215.
- chr6:122,211,648–122,211,811, 1 gene, copy number 5: RNU1-18P.
- chr6:124,962,545–125,092,633, 1 gene, copy number 5 (within-gene range 1–5): RNF217.
- chr6:127,632,958–127,681,555, 5 genes, copy number 5: AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536.
- chr6:128,500,527–128,501,176, 1 gene, copy number 5: AL034349.1.
- chr6:132,538,290–132,539,336, 1 gene, copy number 6: TAAR9.
- chr6:132,868,218–133,107,410, 4 genes, copy number 5 (within-gene range 1–5): HMGB1P13, AL137783.1, LINC00326, RPL23AP46.
- chr6:136,206,478–136,289,851, 3 genes, copy number 5: AL138828.2, MTFR2, BCLAF1.
- chr6:137,867,214–137,903,576, 2 genes, copy number 5: TNFAIP3, AL591468.1.
- chr6:139,135,080–139,277,181, 3 genes, copy number 5 (within-gene range 1–5): HECA, AL031772.1, AL158850.1.
- chr6:146,824,539–147,204,614, 1 gene, copy number 5 (within-gene range 1–5): STXBP5-AS1.
- chr6:147,158,925–147,180,992, 1 gene, copy number 5: LUADT1.
- chr6:147,741,434–147,743,324, 1 gene, copy number 5: AL365271.1.
- chr6:149,304,107–149,304,428, 1 gene, copy number 7: FABP12P1.
- chr6:152,380,546–152,381,564, 1 gene, copy number 5: SYNE1-AS1.
- chr6:153,420,438–153,420,572, 1 gene, copy number 5: RNA5SP225.
- chr6:163,363,210–163,363,463, 1 gene, copy number 5: AL031121.1.
- chr6:165,987,551–165,989,615, 1 gene, copy number 5: LINC00602.

Autosomal genes at a single copy (total copy number 1): 1,879. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
